Somatic mutation profile of tumor specimen TCGA-Q1-A6DT-01A (aliquot TCGA-Q1-A6DT-01A-11D-A32I-09) from TCGA case TCGA-Q1-A6DT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 55.5 years (20,286 days).
Specimen TCGA-Q1-A6DT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31d716f1-f27d-40bf-9658-e03b4f4da9cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A6DT-10A (Blood Derived Normal), aliquot TCGA-Q1-A6DT-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40e72a50-e532-4ef9-b2e7-aec92926be2a

The open-access MAF lists 180 somatic variants for this specimen: 133 protein-altering or splice-affecting, 37 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 37, Nonsense Mutation 10, Intron 4, Frame Shift Del 3, RNA 2, Splice Region 2, 3'UTR 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50960897; called by muse, mutect2, varscan2
- ACTC1 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV51758480; called by muse, mutect2, varscan2
- ADAMTS5 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53177822; called by muse, mutect2, varscan2
- ADCY1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs536487311, COSV52032873; called by muse, mutect2, varscan2
- ADCY10 | c.4774C>G p.Q1592E | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV63239853; called by muse, mutect2, varscan2
- ADGRB3 | c.3775C>A p.P1259T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV53240411; called by muse, mutect2, varscan2
- AFDN | c.4237G>C p.E1413Q | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60042320; called by muse, mutect2, varscan2
- AKIP1 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV55148749; called by muse, mutect2, varscan2
- ARHGAP11A | c.2013G>C p.E671D | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV55705879; called by muse, mutect2, varscan2
- ARMCX2 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs782236145, COSV100168042, COSV100168314, COSV57529376; called by muse, mutect2, varscan2
- ASTN1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs370485432; called by muse, mutect2, varscan2
- B4GALT5 | c.1140del p.E381Sfs*5 | Frame Shift Del (DEL) | VAF 37/105 reads (35%) | catalogued as COSV65493995; called by mutect2, pindel, varscan2
- BTK | c.1841T>A p.L614Q | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV58118700; called by muse, mutect2, varscan2
- CADM4 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV55928525; called by muse, mutect2, varscan2
- CAMSAP2 | c.1475A>T p.E492V (on ENST00000236925 / NM_001297707.2; = p.E481V on NM_203459.3) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV52669167; called by muse, mutect2, varscan2
- CCDC85A | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs750946147, COSV101339393; called by muse, mutect2, varscan2
- CHRM3 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs145638222; called by muse, mutect2, varscan2
- CIC | c.3242C>T p.P1081L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as rs746217053, COSV50557949; called by muse, mutect2, varscan2
- COL14A1 | c.2744T>C p.V915A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52851368; called by muse, mutect2, varscan2
- COL1A2 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011294, COSV51956092; called by muse, mutect2, varscan2
- CYP11B1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1304494959, COSV52825464, COSV52828663; called by muse, mutect2, varscan2
- DBN1 | c.821C>G p.S274W | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52788825, COSV52792976; called by muse, mutect2, varscan2
- DDX60 | c.4090C>T p.L1364F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs774054777, COSV67096167; called by muse, mutect2, varscan2
- DENND2D | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV62958880; called by muse, varscan2
- DEPP1 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.466); catalogued as COSV53573815; called by muse, mutect2, varscan2
- DIDO1 | c.4480G>C p.E1494Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs1227822437, COSV56618722, COSV99825677; called by muse, mutect2, varscan2
- DNAH3 | c.7698G>A p.M2566I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV54514962; called by muse, mutect2
- DNAH8 | c.5530C>G p.P1844A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59437525; called by muse, mutect2, varscan2
- DSG3 | c.1709_1712del p.D570Vfs*12 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs755731286; called by pindel, varscan2
- EDARADD | c.133C>T p.P45S (on ENST00000334232 / NM_145861.4; = p.P35S on NM_080738.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV62062142; called by muse, mutect2, varscan2
- ENHO | c.91T>A p.C31S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV54280198; called by muse, mutect2, varscan2
- ENPP3 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62953822; called by muse, mutect2, varscan2
- FAM9B | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as rs1460559825, COSV59119293; called by muse, mutect2, varscan2
- FBF1 | c.2710G>A p.E904K (on ENST00000586717; = p.E918K on NM_001319193.1) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779091042, COSV59864166; called by muse, mutect2
- FBLN5 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50902065; called by muse, mutect2, varscan2
- FLG | c.8379C>G p.S2793R | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs747057114, COSV64240050, COSV64240779; called by muse, mutect2, varscan2
- FLNA | c.6982C>A p.P2328T (on ENST00000369850 / NM_001110556.2; = p.P2320T on NM_001456.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV61041034; called by muse, mutect2, varscan2
- FOXD4 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV58699479; called by muse, mutect2, varscan2
- GABRA5 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs747206877, COSV59478163; called by muse, mutect2, varscan2
- GOLGA4 | c.2137C>G p.Q713E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV62710174; called by muse, mutect2, varscan2
- GRIN2A | c.4274C>T p.S1425L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs976259560, COSV100410975, COSV58018897; called by muse, mutect2, varscan2
- GRM8 | c.1402C>G p.P468A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV58817431; called by muse, mutect2, varscan2
- GTF3C5 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.381); catalogued as COSV59598979; called by muse, mutect2, varscan2
- H2AC20 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1553759878, COSV58611399, COSV58611757; called by muse, mutect2, varscan2
- HPS6 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54625337; called by muse, mutect2, varscan2
- HYOU1 | c.1446C>G p.I482M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.383); catalogued as COSV68215540; called by muse, mutect2, varscan2
- IGF2BP1 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781338712, COSV51730358; called by muse, mutect2, varscan2
- IL1R2 | c.1050G>A p.W350* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV60206717; called by muse, mutect2, varscan2
- INTS13 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53902024; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56440455; called by muse, mutect2, varscan2
- JADE3 | c.2296G>A p.G766S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54465556; called by muse, mutect2, varscan2
- KLHDC4 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV54507238; called by muse, mutect2, varscan2
- L3MBTL2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as rs1484380791, COSV53432655; called by muse, mutect2, varscan2
- LTBP4 | c.1108G>C p.G370R (on ENST00000308370 / NM_001042544.1; = p.G333R on NM_003573.2) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52579784; called by muse, mutect2, varscan2
- MYO9A | c.7549G>C p.E2517Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV100612718; called by muse, mutect2, varscan2
- NDST3 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.056); catalogued as COSV56616723; called by muse, mutect2, varscan2
- NRXN3 | c.2135G>A p.R712H (on ENST00000335750 / NM_001330195.2; = p.R339H on NM_004796.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766679074, COSV59735181, COSV99046672; called by muse, mutect2, varscan2
- OR10K2 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 155/207 reads (75%) | catalogued as COSV59220915; called by muse, mutect2, varscan2
- OR10S1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775734563, COSV73342735; called by mutect2, varscan2
- OR2J2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754259332, COSV101013291; called by muse, mutect2, varscan2
- OR52W1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs769477980, COSV60950779; called by muse, mutect2, varscan2
- OR5A2 | c.860A>T p.N287I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57390749; called by muse, mutect2, varscan2
- OR9Q2 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61111730; called by muse, mutect2
- PAPPA | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60280819; called by muse, mutect2, varscan2
- PCDH10 | c.141A>C p.K47N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52091446; called by muse, mutect2, varscan2
- PCDH17 | c.3285G>C p.Q1095H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.275); catalogued as COSV64973259; called by muse, mutect2, varscan2
- PEAK1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as COSV100433444, COSV56933425; called by muse, mutect2, varscan2
- PER2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54522746; called by muse, mutect2, varscan2
- PHF8 | c.775G>A p.E259K (on ENST00000357988 / NM_001184896.1; = p.E223K on NM_015107.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV57679764; called by muse, mutect2, varscan2
- PHIP | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV51503331; called by muse, mutect2, varscan2
- PLEKHG4 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV64612341; called by muse, mutect2, varscan2
- PRDM15 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as COSV54151097, COSV54151584; called by muse, mutect2, varscan2
- PRDM9 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57004896, COSV99691605; called by muse, mutect2, varscan2
- PRG4 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100825730, COSV66623529; called by muse, mutect2, varscan2
- PRKD1 | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV59564287; called by muse, mutect2
- PROX2 | c.576C>A p.H192Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV71520025; called by muse, mutect2, varscan2
- PRPF38B | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV100898355, COSV64223686; called by muse, mutect2, varscan2
- PRPF4B | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV61783859; called by muse, mutect2, varscan2
- PSG8 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs138487637; called by muse, mutect2
- PTCH2 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.146); catalogued as rs376329398; called by muse, mutect2, varscan2
- PTGFRN | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV67798198; called by muse, mutect2, varscan2
- PTGFRN | c.2057C>G p.S686* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV67798200; called by muse, mutect2
- PTPRD | c.2173T>A p.S725T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as COSV61937942; called by muse, mutect2, varscan2
- PTPRR | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV51729148; called by muse, varscan2
- PTX4 | c.341G>A p.R114Q (on ENST00000447419 / NM_001328608.2; = p.R109Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs746933052, COSV53515379; called by muse, mutect2, varscan2
- RGS3 | c.2830G>A p.E944K (on ENST00000350696 / NM_001282923.2; = p.E663K on NM_130795.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV59512235; called by muse, mutect2
- ROBO1 | c.1227G>C p.Q409H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV71393088; called by muse, mutect2, varscan2
- ROCK2 | c.3253C>G p.Q1085E | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs376988314, COSV59955821; called by muse, mutect2
- RRNAD1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs775649086, COSV63928805; called by muse, mutect2, varscan2
- RTBDN | c.530G>A p.G177E (on ENST00000393233 / NM_001270444.1; = p.G209E on NM_031429.2) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV59806129; called by muse, mutect2, varscan2
- S1PR3 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766373530, COSV63980396; called by muse, mutect2, varscan2
- SCML4 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749454362, COSV64635059; called by muse, mutect2
- SCO1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs776887702, COSV55135166; called by muse, mutect2, varscan2
- SEMA6D | c.1242G>C p.K414N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60375396; called by muse, mutect2, varscan2
- SLC18A3 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60323105; called by muse, mutect2
- SLC30A1 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV65360845; called by muse, mutect2, varscan2
- SLC9C1 | c.2548G>T p.V850L | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1377832155, COSV59887252; called by muse, mutect2, varscan2
- SLF2 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1282846378, COSV53272616; called by muse, mutect2, varscan2
- SPATA31E1 | c.3751C>T p.Q1251* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57790730; called by muse, mutect2, varscan2
- SPRY1 | c.669C>G p.C223W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59338267; called by muse, mutect2, varscan2
- SPRY3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs779201129, COSV57142048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK17A | c.1199T>A p.F400Y | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100082010; called by muse, mutect2
- SYBU | c.1610C>T p.S537F (on ENST00000276646 / NM_001099754.2; = p.S536F on NM_017786.6) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV52613789; called by muse, mutect2, varscan2
- SYCP2 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs148819194; called by muse, mutect2, varscan2
- SYDE2 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.467); catalogued as COSV52315970, COSV99320237; called by muse, mutect2, varscan2
- SYNE1 | c.20881A>T p.N6961Y (on ENST00000367255 / NM_182961.4; = p.N6890Y on NM_033071.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54953234; called by muse, mutect2, varscan2
- TEDDM1 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV62380420; called by muse, mutect2, varscan2
- THSD7A | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV70263372; called by muse, mutect2, varscan2
- TLE4 | c.1075A>G p.S359G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1040029749, COSV54629958; called by muse, mutect2, varscan2
- TMEM102 | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53439366; called by muse, mutect2, varscan2
- TNFAIP2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60694285; called by muse, mutect2
- TNRC6C | c.2859G>A p.P953= | Splice Region (SNP) | VAF 43/87 reads (49%) | catalogued as COSV100049529; called by muse, mutect2, varscan2
- TRIM32 | c.672G>C p.Q224H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs993542375, COSV57768015; called by muse, mutect2
- TRIM37 | c.1199+1G>A p.X400_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | catalogued as COSV51882863; called by muse, mutect2, varscan2
- TRUB2 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV65759112, COSV65759474; called by muse, varscan2
- TSPAN5 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs928008489, COSV59875079; called by muse, mutect2, varscan2
- TSSC4 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs375904217; called by muse, mutect2, varscan2
- TSSK6 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773772390, COSV53063111; called by muse, mutect2, varscan2
- UQCRB | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV54629573; called by muse, mutect2, varscan2
- USP26 | c.2312A>C p.N771T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs146525524, COSV63708424; called by muse, mutect2, varscan2
- WWOX | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV68349872, COSV68351333; called by muse, mutect2, varscan2
- ZBTB33 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58533622; called by muse, mutect2, varscan2
- ZBTB47 | c.1247G>C p.R416P | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51763354, COSV99233931; called by muse, mutect2, varscan2
- ZFPL1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1468056182, COSV51869122; called by muse, mutect2, varscan2
- ZKSCAN3 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV52852125; called by muse, mutect2, varscan2
- ZNF385D | c.855C>T p.H285= | Splice Region (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55751387; called by muse, mutect2, varscan2
- ZNF609 | c.1661C>G p.S554* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV58581981; called by muse, mutect2, varscan2
- ZNF623 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373149668; called by muse, mutect2, varscan2
- CENPJ | c.1949_1952del p.E650Vfs*17 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- GGNBP2 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OPN1MW | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SLC4A4 | c.2006dup p.L669Ffs*19 (on ENST00000264485 / NM_001098484.3; = p.L625Ffs*19 on NM_003759.4) | Frame Shift Ins (INS) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- TRIM63 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- APOBEC3B | c.690G>C p.L230= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59840649; called by muse, mutect2, varscan2
- ARMC9 | c.717C>T p.H239= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV63020233; called by muse, mutect2, varscan2
- CACNA1S | c.405C>T p.F135= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV62937055; called by muse, mutect2, varscan2
- CHRFAM7A | c.186C>T p.I62= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs752516895, COSV55397190; called by mutect2, varscan2
- COL11A1 | c.4194G>A p.Q1398= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV62179427; called by muse, mutect2, varscan2
- COL21A1 | c.429G>A p.T143= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs143800549, COSV99777556; called by muse, mutect2, varscan2
- DCAF12L2 | c.1245C>T p.D415= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs753659766, COSV63581096; called by muse, mutect2, varscan2
- DDX49 | c.1008C>T p.V336= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs760019445, COSV55355565; called by muse, mutect2, varscan2
- DKK4 | c.436C>T p.L146= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55182297; called by muse, mutect2, varscan2
- ESRRB | c.918C>T p.I306= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV55060349, COSV55060607; called by mutect2, varscan2
- FKTN | c.94T>C p.L32= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV56309128; called by muse, mutect2, varscan2
- GAPVD1 | c.1299T>C p.D433= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs750707747, COSV99782701; called by muse, mutect2, varscan2
- GK2 | c.1347C>T p.P449= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV62626475, COSV62627467; called by muse, mutect2, varscan2
- JPH3 | c.2091C>T p.F697= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1019906565, COSV52466384; called by muse, mutect2, varscan2
- KCNB2 | c.177G>A p.T59= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs566076958, COSV73049681; called by muse, mutect2, varscan2
- LZTS3 | c.927C>T p.F309= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs577156264, COSV61277422; called by muse, mutect2
- MAGEE1 | c.114T>C p.A38= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as COSV63909579; called by muse, mutect2, varscan2
- MAS1L | c.987C>G p.L329= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV65808779; called by muse, mutect2, varscan2
- MUC2 | c.2853G>A p.T951= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs755099001; called by muse, mutect2, varscan2
- MYO7B | c.3495C>T p.F1165= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV67346419; called by muse, mutect2, varscan2
- PADI4 | c.978G>C p.L326= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV64923751; called by muse, mutect2, varscan2
- PPIP5K2 | c.1407T>C p.Y469= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV58604704; called by muse, mutect2, varscan2
- PRKCZ | c.894G>A p.Q298= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV66066779; called by muse, mutect2, varscan2
- PRSS16 | c.618C>G p.V206= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100041552; called by muse, mutect2, varscan2
- PTPRM | c.2254C>T p.L752= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV59853399; called by muse, mutect2, varscan2
- PTX3 | c.639C>T p.V213= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV99904779; called by muse, mutect2, varscan2
- SAMSN1 | c.1104C>T p.I368= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53469905; called by muse, mutect2, varscan2
- SLC16A3 | c.924G>A p.A308= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs780404859, COSV58364259; called by muse, mutect2, varscan2
- SLC8A1 | c.1485C>T p.L495= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100244686; called by muse, mutect2, varscan2
- STAT5A | c.180C>G p.L60= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV61806373; called by muse, mutect2, varscan2
- SYNPO2L | c.2037C>G p.L679= (on ENST00000394810 / NM_001114133.3; = p.L455= on NM_024875.5) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV65736600; called by muse, mutect2, varscan2
- TARS3 | c.1743G>T p.P581= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100254673, COSV60107827; called by muse, mutect2, varscan2
- TRUB2 | c.786C>T p.F262= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV65759531; called by muse, varscan2
- TRUB2 | c.642C>T p.L214= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV65759535; called by muse, mutect2, varscan2
- VWA2 | c.1677C>T p.L559= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs1299208803, COSV53905904; called by muse, mutect2, varscan2
- ZMIZ2 | c.1951C>T p.L651= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV54807080; called by muse, mutect2, varscan2
- ZNF665 | c.237C>T p.S79= (on ENST00000600412; = p.S144= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67214425; called by muse, mutect2, varscan2
- ANKRD13D | c.*563G>C | 3'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as COSV57751651; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1449C>T | 3'UTR (SNP) | VAF 12/22 reads (55%) | catalogued as COSV57542253; called by muse, mutect2, varscan2
- CCDC18 | c.-3+233C>T | Intron (SNP) | VAF 18/44 reads (41%) | catalogued as COSV58142514; called by muse, mutect2, varscan2
- MAGEA5 | n.205T>A | RNA (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- MYB | c.1203+1123G>C | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as COSV57197387; called by muse, mutect2, varscan2
- NBPF25P | n.1541C>T | RNA (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- OR1N2 | c.-3G>A | 5'UTR (SNP) | VAF 10/65 reads (15%) | catalogued as COSV65460181; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163887 G>A | 5'Flank (SNP) | VAF 46/273 reads (17%) | catalogued as rs745632930; called by muse, mutect2, varscan2
- TIPIN | c.475+1812C>G | Intron (SNP) | VAF 19/57 reads (33%) | catalogued as COSV56019819; called by muse, mutect2, varscan2
- TTN | c.10360+2647G>A | Intron (SNP) | VAF 27/90 reads (30%) | catalogued as rs571048846, COSV59983479; called by muse, mutect2, varscan2
